Gene-level copy-number profile of specimen HCM-CSHL-0802-C67-85B from HCMI case HCM-CSHL-0802-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; Tumor grade: G3.
Specimen HCM-CSHL-0802-C67-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d9eb9dcd-c5fd-4066-b140-308f2656d1f5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0802-C67-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/8417d4c4-ce20-4438-a2a1-64cf8e02d569

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 171; copy number 1: 36,937; copy number 2: 18,112; copy number 3: 2,854; copy number 4: 566; copy number 5: 156; copy number 7: 14; copy number 10: 46; copy number 11: 3; copy number 12: 3; copy number 14: 37; copy number 15: 1; copy number 19: 8.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 3,688 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:29,488,193–29,496,893, 1 gene, copy number 3: AL671862.1.
- chr1:83,575,776–83,861,023, 2 genes, copy number 3: LINC01725, AL035706.1.
- chr1:85,729,233–86,156,943, 3 genes, copy number 3: COL24A1, RNA5SP51, AC104455.1.
- chr3:72,888,046–75,785,583, 54 genes, copy number 4–5: GXYLT2, Metazoa_SRP, FTH1P23, PPP4R2, RNU7-19P, EBLN2, RNU6-557P, RNU2-64P, CCDC75P1, RNU6-1270P, PDZRN3, RNU7-119P, PDZRN3-AS1, AC117489.1, AC108725.1, LINC02005, Metazoa_SRP, LINC02047, AC016930.1, AKR1B1P2, CNTN3, NIPA2P2, RN7SL294P, MIR4444-2, AC117481.1, HNRNPA3P6, MYLKP1, OR7E66P, OR7E22P, OR7E55P, AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1, OR7E121P, UNC93B3, RPL23AP49, AC108724.2, CLUHP10, MIR1324, AGGF1P3, RARRES2P1, FRG2C, DUX4L26, LINC00960, ZNF717, MIR4273.
- chr3:86,816,740–88,467,594, 22 genes, copy number 3: AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA.
- chr3:88,948,142–89,048,434, 2 genes, copy number 3: ICE2P2, GAPDHP50.
- chr5:58,198–45,895,970, 679 genes, copy number 3–5 (broad region; genes not listed).
- chr12:11,516,425–11,521,686, 1 gene, copy number 3: AC007450.2.
- chr12:41,188,320–43,661,101, 39 genes, copy number 3: PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17.
- chr12:44,508,275–47,079,959, 35 genes, copy number 3–7 (within-gene range 1–7): NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1, AMIGO2.
- chr13:18,467,172–20,232,365, 67 genes, copy number 3 (broad region; genes not listed).
- chr13:21,298,139–41,961,120, 358 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr13:52,703,264–114,337,626, 638 genes, copy number 3 (broad region; genes not listed).
- chr15:20,516,252–20,541,800, 2 genes, copy number 3: AC023310.1, GOLGA6L6.
- chr15:20,657,638–20,688,408, 1 gene, copy number 3 (within-gene range 2–3): NBEAP1.
- chr15:20,890,206–20,935,658, 4 genes, copy number 3–4: AC012414.5, AC037471.2, ZNF519P2, NF1P1.
- chr17:31,830,731–32,881,070, 50 genes, copy number 3–4: AC004253.2, COPRS, UTP6, AC004253.1, SUZ12, RNA5SP437, AC090616.3, LRRC37B, AC090616.4, SH3GL1P1, AC090616.6, AC090616.2, AC090616.5, AC090616.1, WDR45BP1, AC116407.2, AC116407.1, RHOT1, ARGFXP2, AC116407.4, AC116407.3, UBL5P2, RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5, AC005899.8, AC005899.1, AC005899.2, PSMD11, Y_RNA, CDK5R1, MYO1D, AC079336.5, AC079336.7, AC079336.2, AC079336.1, AC079336.6, AC079336.4, AC079336.3, AC025211.1, Y_RNA, AC084809.1.
- chr17:36,450,146–40,061,215, 134 genes, copy number 3–19 (within-gene range 1–19) (broad region; genes not listed).
- chr18:45,034–15,330,282, 367 genes, copy number 3 (broad region; genes not listed).
- chr20:87,250–41,196,801, 836 genes, copy number 3–4 (within-gene range 2–4) (broad region; genes not listed).
- chr20:41,196,647–41,197,157, 2 genes, copy number 3 (within-gene range 2–3): AL022394.1, RPL23AP81.
- chr21:34,513,142–42,925,646, 176 genes, copy number 3 (broad region; genes not listed).
- chr22:18,846,811–19,291,719, 35 genes, copy number 3: AC008132.1, BCRP7, FAM230F, AC008103.1, DGCR6, AC007326.4, PRODH, AC007326.5, AC007326.2, DGCR5, AC007326.3, DGCR5, AC007326.1, AC000095.2, AC000095.1, FAM246C, CA15P1, DGCR2, Y_RNA, DGCR11, AC004461.1, AC004461.2, AC004471.1, AC004471.2, TSSK1A, ESS2, TSSK2, GSC2, LINC01311, SLC25A1, CLTCL1, AC000072.1, AC000081.1, AC000081.2, KRT18P62.
- chr22:19,714,503–19,854,939, 6 genes, copy number 3 (within-gene range 1–3): SEPTIN5, AC000093.1, GP1BB, TBX1, GNB1L, AC000089.1.
- chr22:20,602,595–20,964,679, 13 genes, copy number 3: SMPD4P1, IGLL4P, SLC9A3P2, ABHD17AP4, POM121L4P, BCRP5, TMEM191A, PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637.
- chr22:21,045,960–21,070,097, 2 genes, copy number 3: LRRC74B, TUBA3GP.
- chr22:34,017,422–35,087,387, 8 genes, copy number 3: LINC01643, Z68323.1, AL021877.1, AL021877.2, Z82196.1, Z82196.2, LINC02885, ISX.
- chr22:35,501,861–37,029,822, 54 genes, copy number 3: AL022334.1, AL022334.2, RASD2, MB, AL049747.1, APOL6, AL049748.1, MRPS16P3, APOL5, RBFOX2, NDUFA9P1, Z82217.1, Z95114.4, Z95114.1, Z95114.2, Z95114.3, APOL3, MTCO1P20, MTCO2P20, MTATP6P20, MTCO3P20, MTCYBP34, MTND1P10, APOL4, APOL2, APOL1, MYH9, MIR6819, Z82215.1, FO393418.1, RPS15AP38, Y_RNA, AL022313.2, TXN2, FOXRED2, EIF3D, AL022313.1, AL022313.3, CACNG2, AL022313.4, AL049749.1, IFT27, Z80897.1, PVALB, Z82185.1, NCF4-AS1, NCF4, CSF2RB, CSF2RBP1, LL22NC01-81G9.3, TEX33, TST, Y_RNA, MPST.
- chr22:38,084,900–38,110,684, 1 gene, copy number 3 (within-gene range 2–3): BAIAP2L2.
- chr22:38,111,495–38,281,289, 7 genes, copy number 3: PLA2G6, AL022322.2, MAFF, TMEM184B, AL020993.1, RN7SL704P, Metazoa_SRP.
- chr22:39,091,586–39,437,060, 16 genes, copy number 3: AL031846.1, APOBEC3H, CBX7, COX5BP7, AL031846.2, FUNDC2P4, PDGFB, AL031590.1, AL022326.1, RPL3, SNORD83B, SNORD83A, SNORD43, SYNGR1, AL022326.2, TAB1.
- chr22:39,743,044–40,682,814, 22 genes, copy number 3: ENTHD1, MTFR2P2, RN7SKP210, UQCRFS1P1, GRAP2, Z82206.1, FAM83F, Z83847.1, TNRC6B, RPL7P52, ADSL, AL022238.3, SGSM3, SGSM3-AS1, MRTFA, AL022238.2, AL022238.1, MRTFA-AS1, COX6B1P3, RPL4P6, GAPDHP37, MCHR1.
- chr22:42,508,344–42,649,392, 10 genes, copy number 3 (within-gene range 2–3): RRP7A, SERHL2, RRP7BP, RN7SKP80, RNU6-513P, POLDIP3, RNU12, Z93241.1, CYB5R3, ATP5MGL.
- chr22:43,038,585–43,092,524, 3 genes, copy number 3: TTLL1-AS1, TTLL1, AL022237.1.
- chr22:43,516,107–43,892,013, 7 genes, copy number 3: EFCAB6-AS1, EFCAB6, Z97055.1, HMGN2P9, Z97055.2, SULT4A1, PNPLA5.
- chr22:50,309,030–50,327,012, 3 genes, copy number 3: DENND6B, CR559946.1, CR559946.2.
- chr22:50,481,543–50,801,309, 28 genes, copy number 3: ADM2, MIOX, LMF2, NCAPH2, SCO2, U62317.1, TYMP, ODF3B, U62317.3, KLHDC7B-DT, KLHDC7B, SYCE3, CPT1B, CHKB-CPT1B, CHKB, CHKB-DT, U62317.2, MAPK8IP2, ARSA, Y_RNA, SHANK3, RNU6-409P, AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Autosomal genes at a single copy (total copy number 1): 34,252. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
